Somatic mutation profile of tumor specimen TCGA-28-5211-01C (aliquot TCGA-28-5211-01C-11D-1845-08) from TCGA case TCGA-28-5211, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 42.5 years (15,507 days).
Specimen TCGA-28-5211-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d48389e4-d62d-40ab-b7de-9f24a15d1f8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5211-10B (Blood Derived Normal), aliquot TCGA-28-5211-10B-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c1a7bd3-c494-4c79-acc1-9bab05524d9c

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Intron 1, 5'UTR 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs72653787, CM073961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.6344G>A p.S2115N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV64674453; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs147113160; called by mutect2, varscan2
- ARHGAP6 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.28); catalogued as COSV61629547; called by muse, mutect2, varscan2
- BMI1 | c.102T>G p.C34W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64959210; called by muse, mutect2, varscan2
- COL6A3 | c.5404G>A p.V1802I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs1347291834, COSV55094012; called by mutect2, varscan2
- ENGASE | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV56136123; called by muse, mutect2, varscan2
- GJD2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 41/177 reads (23%) | catalogued as rs749647277, COSV51747639; called by muse, mutect2, varscan2
- GRB10 | c.1265C>T p.T422M (on ENST00000398812; = p.T376M on NM_001001549.3) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs932870989, COSV60010417; called by mutect2, varscan2
- HCN1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV57517065; called by mutect2, varscan2
- LAMA2 | c.7690C>G p.L2564V | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV70350282, COSV70351115, COSV70351952; called by muse, mutect2, varscan2
- LRP1 | c.12400T>C p.S4134P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV54514870; called by muse, mutect2, varscan2
- LUM | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754001312, COSV57128073, COSV57128196; called by muse, mutect2, varscan2
- MAGEC2 | c.165C>A p.F55L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55999842, COSV99910036; called by mutect2, varscan2
- MCTP2 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs199555430; called by mutect2, varscan2
- NEB | c.18436C>A p.Q6146K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51426616; called by muse, mutect2, varscan2
- PIK3R5 | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs148129311; called by mutect2, varscan2
- PPM1J | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs113935705; called by muse, mutect2, varscan2
- PRRC2A | c.3278A>G p.E1093G | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65687252; called by muse, mutect2, varscan2
- PTPRH | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs1170863012, COSV54746558; called by mutect2, varscan2
- SLC1A6 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs751282250, COSV55668860, COSV55674280; called by muse, mutect2, varscan2
- SYNE1 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs756572630, COSV55010821, COSV55097463; called by muse, mutect2, varscan2
- SYNE2 | c.6880-1G>A p.X2294_splice | Splice Site (SNP) | VAF 18/66 reads (27%) | catalogued as COSV59954774; called by muse, mutect2, varscan2
- TCHH | c.2881C>T p.R961W | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV64275542; called by muse, mutect2, varscan2
- TLR6 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs374845111; called by mutect2, varscan2
- TRAIP | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58914896; called by muse, mutect2, varscan2
- CDON | c.2859del p.P954Lfs*14 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- DLC1 | c.2265G>A p.T755= (on ENST00000276297 / NM_001348081.2; = p.T318= on NM_006094.5) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs138749997, COSV52309764; called by mutect2, varscan2
- EVA1A | c.288C>T p.S96= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1431841835, COSV52059458; called by muse, mutect2, varscan2
- HTR5A | c.654C>T p.F218= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1033886701, COSV55284317, COSV55284738; called by muse, mutect2, varscan2
- OR1D5 | c.114G>A p.T38= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs770713746, COSV101643424; called by muse, mutect2, varscan2
- OR2G2 | c.561C>A p.L187= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV60740899; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.801G>A p.E267= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV59129993; called by muse, mutect2, varscan2
- AGR2 | c.-1C>T | 5'UTR (SNP) | VAF 7/37 reads (19%) | catalogued as rs748127944, COSV101290813; called by muse, mutect2, varscan2
- PIK3C2B | c.934-1506A>T | Intron (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
